Gene-level copy-number profile of tumor specimen TCGA-PN-A8MA-01A from TCGA case TCGA-PN-A8MA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 43.6 years (15,918 days).
Specimen TCGA-PN-A8MA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.f22d5b86-dfd8-420a-8a41-66fe70c320ba.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PN-A8MA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/53030e41-fc4d-4c9d-8b8b-76f9fee27357

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 17; copy number 2: 1,634; copy number 3: 12,896; copy number 4: 27,770; copy number 5: 4,704; copy number 6: 6,942; copy number 7: 3,885; copy number 8: 151; copy number 9: 1,737; copy number 10: 43; copy number 47: 2; copy number 49: 9; copy number 51: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-PN-A8MA-01A-11D-A36I-01): tumor purity 0.78, ploidy 4.36, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,821 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:4,792,944–4,885,917, 1 gene, copy number 51 (within-gene range 5–51): RCL1.
- chr9:4,850,297–5,629,748, 29 genes, copy number 51 (within-gene range 4–51): MIR101-2, AL158147.1, HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2.
- chr14:36,647,083–36,679,362, 2 genes, copy number 47: AL079303.1, PAX9.
- chr14:37,197,913–38,041,442, 9 genes, copy number 49 (within-gene range 4–49): MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517.
- chr19:52,594,060–52,690,496, 1 gene, copy number 9 (within-gene range 7–9): ZNF83.
- chr19:52,650,437–56,530,221, 321 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
